Somatic mutation profile of tumor specimen TCGA-KQ-A41O-01A (aliquot TCGA-KQ-A41O-01A-12D-A34U-08) from TCGA case TCGA-KQ-A41O, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 84.3 years (30,774 days).
Specimen TCGA-KQ-A41O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01c01827-00cf-4728-b2bb-441f94844b3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KQ-A41O-10D (Blood Derived Normal), aliquot TCGA-KQ-A41O-10D-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8adcb1a-8a48-477a-a0b9-b70a6763c5cd

The open-access MAF lists 277 somatic variants for this specimen: 203 protein-altering or splice-affecting, 67 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 174, Silent 67, Nonsense Mutation 19, Intron 4, Frame Shift Del 3, Splice Site 3, Splice Region 2, RNA 2, Frame Shift Ins 1, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCK | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.281); catalogued as rs748964205, CM149035, CM154280, COSV60785687; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 37/89 reads (42%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 33/36 reads (92%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCD2 | c.1305A>T p.R435S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV58049162; called by muse, mutect2, varscan2
- AC006059.2 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.685); catalogued as rs1436017127, COSV100045795, COSV59605627; called by muse, mutect2, varscan2
- AGBL1 | c.1442C>G p.S481C | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV66847459, COSV66865761; called by muse, mutect2, varscan2
- AGO1 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.232); catalogued as COSV64594628; called by muse, mutect2, varscan2
- AK2 | c.363G>A p.M121I (on ENST00000354858; = p.M163I on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 151/334 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.642); catalogued as COSV61466064; called by muse, mutect2, varscan2
- AKAP13 | c.5842G>A p.D1948N (on ENST00000394518 / NM_007200.5; = p.D1952N on NM_006738.6) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63447474; called by muse, mutect2, varscan2
- AKAP7 | c.742A>T p.I248F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV53833257; called by muse, mutect2, varscan2
- ANGPT1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52429280; called by muse, mutect2, varscan2
- ANK3 | c.8272G>A p.V2758I | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs150537210; called by muse, mutect2, varscan2
- ANKH | c.782T>C p.F261S | Missense Mutation (SNP) | VAF 173/231 reads (75%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV52476235; called by muse, mutect2, varscan2
- AP4B1 | c.1741G>T p.A581S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV56723061; called by muse, mutect2, varscan2
- AREL1 | c.2291G>C p.G764A | Missense Mutation (SNP) | VAF 97/139 reads (70%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV62665292; called by muse, mutect2, varscan2
- ARHGAP18 | c.1756C>G p.L586V | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV63763224; called by muse, mutect2, varscan2
- ARRB2 | c.358-1G>C p.X120_splice | Splice Site (SNP) | VAF 108/112 reads (96%) | catalogued as COSV52616381; called by muse, mutect2, varscan2
- ATP1A1 | c.1773G>C p.M591I | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV55189321; called by muse, mutect2, varscan2
- BCORL1 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 164/170 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs1420562958, COSV54388958, COSV99499855; called by muse, mutect2, varscan2
- BDP1 | c.6845A>G p.D2282G | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV62428606; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3625C>G p.Q1209E | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV63243796; called by muse, mutect2, varscan2
- BUB1 | c.1254G>C p.Q418H | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); catalogued as COSV57061016; called by muse, mutect2, varscan2
- CBLL1 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.871); catalogued as COSV56027851; called by muse, varscan2
- CBLL1 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); catalogued as COSV56027861; called by muse, varscan2
- CCDC34 | c.1080G>C p.R360S | Missense Mutation (SNP) | VAF 105/111 reads (95%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV60820018; called by muse, mutect2, varscan2
- CCT3 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs542700328, COSV55287290; called by muse, mutect2, varscan2
- CDCA2 | c.608G>A p.R203K | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.342); catalogued as COSV57944026; called by muse, mutect2, varscan2
- CDH23 | c.105C>A p.F35L | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV54923147; called by muse, mutect2, varscan2
- CDH6 | c.1604C>G p.S535* | Nonsense Mutation (SNP) | VAF 335/394 reads (85%) | catalogued as COSV99418546; called by muse, mutect2, varscan2
- CDH8 | c.2392G>C p.E798Q | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.529); catalogued as COSV54845495, COSV54882936, COSV54888247; called by muse, mutect2, varscan2
- CDK14 | c.854G>C p.S285T (on ENST00000380050 / NM_001287135.2; = p.S267T on NM_012395.3) | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.191); catalogued as COSV56022798; called by muse, mutect2, varscan2
- CEBPZ | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50016850; called by muse, mutect2, varscan2
- CELSR2 | c.7031G>A p.R2344H | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs570931149, COSV54766092; called by muse, mutect2, varscan2
- CEP104 | c.2759G>A p.R920K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); catalogued as COSV65515919; called by muse, varscan2
- CEP170 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV60505531, COSV60509429; called by muse, mutect2, varscan2
- CEP290 | c.5265G>C p.M1755I | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV58348143; called by muse, mutect2, varscan2
- CFAP20DC | c.1321C>A p.L441I (on ENST00000482387 / NM_001351530.2; = p.L316I on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV55915453; called by muse, mutect2, varscan2
- CFAP61 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 145/248 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55617907; called by muse, mutect2, varscan2
- CHD3 | c.3178G>C p.G1060R | Missense Mutation (SNP) | VAF 62/62 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57872170, COSV57877830; called by muse, mutect2, varscan2
- CHRNB3 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.08); catalogued as COSV51492900; called by muse, mutect2, varscan2
- CIAO3 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV52400498; called by muse, mutect2, varscan2
- CLASP1 | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99753976; called by muse, mutect2
- CLNS1A | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV54439474; called by muse, mutect2, varscan2
- CNTN2 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as COSV59347832; called by muse, mutect2, varscan2
- COA8 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as COSV56027321, COSV99914704; called by muse, mutect2, varscan2
- COL22A1 | c.4000T>A p.S1334T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.084); catalogued as COSV57321365; called by muse, mutect2, varscan2
- CPD | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 113/146 reads (77%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs770682221, COSV56710402; called by muse, mutect2, varscan2
- CPNE3 | c.780C>G p.S260R | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.183); catalogued as COSV52203549; called by muse, mutect2, varscan2
- CRABP1 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55115287; called by muse, mutect2, varscan2
- CREBRF | c.1274C>A p.S425* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV51632494, COSV99755602; called by muse, mutect2, varscan2
- CRYBG1 | c.2149C>G p.L717V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64810329; called by muse, mutect2, varscan2
- CSMD1 | c.7291C>A p.P2431T (on ENST00000520002; = p.P2430T on NM_033225.6) | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as COSV59277144; called by muse, mutect2, varscan2
- CSMD3 | c.6229C>T p.Q2077* (on ENST00000297405 / NM_001363185.1; = p.Q1973* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 50/111 reads (45%) | catalogued as COSV52165547, COSV52353929; called by muse, mutect2, varscan2
- DCUN1D4 | c.793G>C p.D265H (on ENST00000334635 / NM_001287757.1; = p.D230H on NM_015115.3) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100584537, COSV58120434; called by muse, mutect2, varscan2
- DDX54 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs760850225, COSV58371630; called by muse, mutect2, varscan2
- DHX8 | c.1772G>C p.G591A | Missense Mutation (SNP) | VAF 71/112 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52250702; called by muse, mutect2, varscan2
- DMD | c.5878G>C p.E1960Q | Missense Mutation (SNP) | VAF 41/42 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as CM115774, COSV100817963, COSV63732656; called by muse, mutect2, varscan2
- DMRT2 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 59/63 reads (94%) | catalogued as rs1384454829, COSV99425984; called by muse, mutect2, varscan2
- DNAJC6 | c.685A>G p.K229E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV54768963; called by muse, mutect2, varscan2
- DNM1L | c.500G>C p.R167T | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV56771874; called by muse, mutect2, varscan2
- DOCK3 | c.373_377del p.L125Kfs*17 | Frame Shift Del (DEL) | VAF 19/139 reads (14%) | catalogued as COSV56500649; called by mutect2, pindel, varscan2
- EFCAB5 | c.3976C>G p.L1326V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1006922509, COSV100299741, COSV57925390; called by muse, varscan2
- EGR3 | c.858C>G p.F286L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57832736; called by muse, mutect2, varscan2
- EML1 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 90/125 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV51740843; called by muse, mutect2, varscan2
- ENOSF1 | c.1258G>A p.E420K (on ENST00000340116 / NM_001354066.2; = p.E386K on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99201016; called by muse, mutect2, varscan2
- ENPP3 | c.1969C>G p.L657V | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.219); catalogued as COSV62952749; called by muse, mutect2, varscan2
- EPG5 | c.1291C>G p.Q431E | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV56344129; called by muse, mutect2, varscan2
- EPHA2 | c.128G>A p.W43* | Nonsense Mutation (SNP) | VAF 58/139 reads (42%) | catalogued as COSV100626062; called by muse, mutect2, varscan2
- EPM2AIP1 | c.83T>C p.V28A | Missense Mutation (SNP) | VAF 82/104 reads (79%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV51613806; called by muse, mutect2, varscan2
- ESRP2 | c.1335G>C p.L445F (on ENST00000565858 / NM_001365264.1; = p.L435F on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52171775; called by muse, mutect2, varscan2
- EXOSC8 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as rs1214554467, COSV99524008, COSV99524016; called by muse, mutect2, varscan2
- FAM153A | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV100646968; called by mutect2, varscan2
- FURIN | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs754366900, COSV51574462; called by muse, mutect2, varscan2
- GABRQ | c.1512G>C p.L504F | Missense Mutation (SNP) | VAF 40/45 reads (89%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.656); catalogued as COSV64780703; called by muse, mutect2, varscan2
- GALNT1 | c.858C>G p.V286= | Splice Region (SNP) | VAF 63/106 reads (59%) | catalogued as COSV52450606; called by muse, mutect2, varscan2
- GMDS | c.631A>T p.S211C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66428136; called by muse, mutect2, varscan2
- GTF2E1 | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 103/136 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV52202991; called by muse, mutect2, varscan2
- GTPBP2 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV61075566; called by muse, mutect2, varscan2
- H3C3 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as rs774188493, COSV100778300, COSV63550622; called by muse, mutect2, varscan2
- HELZ2 | c.7586C>G p.S2529C (on ENST00000467148 / NM_001037335.2; = p.S1960C on NM_033405.3) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV100918779; called by muse, mutect2
- HSPG2 | c.2569G>A p.G857R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770438141, COSV65968743; called by muse, mutect2, varscan2
- HSPH1 | c.690C>G p.F230L | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs143448335; called by muse, mutect2
- HTR1A | c.1155C>G p.I385M | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60499675; called by muse, mutect2, varscan2
- ICAM3 | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142276897; called by muse, mutect2, varscan2
- ICAM3 | c.1021C>G p.R341G | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV50328224; called by muse, mutect2, varscan2
- IFT172 | c.2458G>C p.E820Q | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.481); catalogued as COSV53129063, COSV99562614, COSV99563780; called by muse, mutect2, varscan2
- IGSF3 | c.1167C>A p.F389L | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV59584900; called by muse, mutect2, varscan2
- INTS7 | c.591G>T p.L197F | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65343595; called by muse, mutect2, varscan2
- JAM3 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745951708, COSV54449892; called by muse, mutect2, varscan2
- JARID2 | c.1433G>A p.R478K | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100522215, COSV59184673; called by muse, mutect2, varscan2
- KDM6A | c.2995G>T p.E999* | Nonsense Mutation (SNP) | VAF 54/57 reads (95%) | catalogued as COSV65038034, COSV65040758; called by muse, mutect2, varscan2
- KIF13A | c.4108G>C p.E1370Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52441520; called by muse, mutect2, varscan2
- KIF21A | c.1378C>G p.Q460E | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.977); catalogued as COSV62766599; called by muse, mutect2, varscan2
- KIF4B | c.3646C>G p.L1216V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.214); catalogued as COSV70527012, COSV70529180; called by muse, mutect2, varscan2
- KLHL40 | c.269A>T p.Y90F | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55132464; called by muse, mutect2, varscan2
- KRIT1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.952); catalogued as CM081683, COSV60666611; called by muse, mutect2, varscan2
- KRTAP1-3 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 76/102 reads (75%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV60335481, COSV60336603; called by muse, mutect2, varscan2
- LIPA | c.827G>C p.R276T | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51077798; called by muse, mutect2, varscan2
- LRRK1 | c.1176G>C p.L392F | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52600147; called by muse, mutect2, varscan2
- LY75 | c.4945G>C p.E1649Q | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV55101488; called by muse, mutect2, varscan2
- MAGI2 | c.2503G>A p.G835S | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs762040290, COSV62631468; called by muse, mutect2, varscan2
- MAP3K4 | c.3010G>T p.A1004S | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV62329854, COSV62331269; called by muse, mutect2, varscan2
- MAP4K3 | c.1998C>G p.I666M | Missense Mutation (SNP) | VAF 92/155 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55709491; called by muse, mutect2, varscan2
- MAU2 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 86/154 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV53233440; called by muse, mutect2, varscan2
- MCTP1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56502642; called by muse, mutect2, varscan2
- MLX | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 67/91 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as rs761350836, COSV53815937; called by muse, mutect2, varscan2
- MSRB2 | c.265C>G p.H89D | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV64737063; called by muse, mutect2, varscan2
- MTA2 | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 43/44 reads (98%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.017); catalogued as COSV53468520; called by muse, mutect2, varscan2
- MUC20 | c.1581G>T p.R527S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as rs750854832, COSV57846796; called by muse, mutect2
- MYEOV | c.611G>C p.R204P | Missense Mutation (SNP) | VAF 199/249 reads (80%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.022); catalogued as COSV100456719, COSV58293368; called by muse, mutect2, varscan2
- MYPN | c.3932C>G p.S1311C | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV62731299; called by muse, mutect2, varscan2
- NAPSA | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as rs749576537, COSV53796627; called by muse, mutect2, varscan2
- NBEAL2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1470257385, COSV99435396; called by muse, mutect2, varscan2
- NBEAL2 | c.5299C>T p.Q1767* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as rs754780191, CM1510952, COSV99435400; called by muse, mutect2, varscan2
- NOL10 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs531990647, COSV62042583, COSV62043702; called by muse, varscan2
- NOMO1 | c.3130G>A p.D1044N | Missense Mutation (SNP) | VAF 71/119 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as rs771995798, COSV55057048; called by muse, mutect2, varscan2
- NRDC | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.093); catalogued as COSV61401240; called by muse, mutect2, varscan2
- NUAK2 | c.31G>C p.G11R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV65680673, COSV65682550; called by muse, mutect2, varscan2
- NUDT14 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 75/123 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV59650109; called by muse, mutect2, varscan2
- NXPH4 | c.876G>C p.Q292H | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61072954; called by muse, mutect2, varscan2
- OR7G2 | c.554T>C p.L185S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs774875374, COSV59687252; called by muse, varscan2
- OSBPL3 | c.625G>T p.V209F | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV57652041; called by muse, mutect2, varscan2
- OTOF | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as COSV55494786; called by muse, mutect2, varscan2
- P2RX1 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 90/95 reads (95%) | SIFT tolerated (0.38); PolyPhen benign (0.431); catalogued as rs764737772, COSV50113885; called by muse, mutect2, varscan2
- P4HB | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 80/106 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV100515880, COSV58939761; called by muse, mutect2, varscan2
- PAPOLB | c.185G>T p.R62M | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68198877; called by muse, mutect2, varscan2
- PARP15 | c.869C>G p.S290C (on ENST00000464300 / NM_001113523.3; = p.S56C on NM_152615.2) | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs367702270; called by muse, mutect2, varscan2
- PARP8 | c.239A>T p.E80V | Missense Mutation (SNP) | VAF 115/153 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV55855262; called by muse, mutect2, varscan2
- PDE1B | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 65/134 reads (49%) | catalogued as COSV54494734; called by muse, mutect2, varscan2
- PDE4D | c.943G>C p.E315Q (on ENST00000340635 / NM_001104631.2; = p.E179Q on NM_006203.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV57714136; called by muse, mutect2, varscan2
- PEAK1 | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV56930084, COSV56936742; called by muse, mutect2, varscan2
- PHF3 | c.1147A>T p.I383F | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as COSV50312911; called by muse, mutect2, varscan2
- PHKG2 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 124/381 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as rs564053771, COSV60310804; called by muse, mutect2, varscan2
- PI4K2A | c.1257G>C p.Q419H | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65700950; called by muse, mutect2, varscan2
- PITX2 | c.349G>A p.E117K (on ENST00000354925 / NM_001204397.1; = p.E124K on NM_000325.6) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60740015, COSV60741296; called by muse, mutect2, varscan2
- PIWIL2 | c.1859A>T p.E620V | Missense Mutation (SNP) | VAF 110/223 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV63249412; called by muse, mutect2, varscan2
- PNPLA6 | c.3134C>T p.S1045L (on ENST00000414982 / NM_001166111.2; = p.S997L on NM_006702.5) | Missense Mutation (SNP) | VAF 102/186 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs541098659, CM140440, COSV55372991; called by muse, mutect2, varscan2
- PRDM2 | c.2210C>T p.T737I | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52442421; called by muse, mutect2, varscan2
- PRRT3 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 88/124 reads (71%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs776359469, COSV55976196; called by muse, mutect2
- PWWP3A | c.305G>A p.G102D (on ENST00000627377; = p.G101D on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.738); catalogued as COSV60900628; called by muse, mutect2, varscan2
- QPCT | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 75/122 reads (61%) | catalogued as COSV58121870; called by muse, mutect2, varscan2
- RAB2B | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 88/168 reads (52%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs776432456, COSV67235182; called by muse, mutect2, varscan2
- RAD54L2 | c.1639C>G p.R547G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56576778; called by muse, mutect2, varscan2
- RAPGEF3 | c.1918G>A p.E640K (on ENST00000389212; = p.E598K on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV50197859; called by muse, mutect2, varscan2
- RBM26 | c.787C>G p.H263D | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57390836, COSV57395821; called by muse, mutect2, varscan2
- RDH16 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV62457831; called by muse, mutect2, varscan2
- RFX2 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.112); catalogued as rs200247864, COSV57938834; called by muse, mutect2, varscan2
- RFX5 | c.1302_1303del p.E435Sfs*5 | Frame Shift Del (DEL) | VAF 74/359 reads (21%) | catalogued as COSV51837886; called by mutect2, pindel, varscan2
- RIPOR3 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 49/92 reads (53%) | catalogued as COSV99246141; called by muse, mutect2, varscan2
- RIPOR3 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV50385525; called by muse, mutect2, varscan2
- RNF31 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs759512304, COSV53758257, COSV53758349; called by muse, mutect2, varscan2
- RPIA | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV52167882; called by muse, mutect2, varscan2
- RSC1A1 | c.204G>C p.K68N | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.22); catalogued as COSV60778858; called by muse, mutect2, varscan2
- RUVBL2 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as COSV55484070; called by muse, mutect2, varscan2
- RYR1 | c.11206G>A p.E3736K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV62087457; called by muse, mutect2, varscan2
- RYR2 | c.4210A>T p.R1404* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100767546, COSV100769155; called by muse, mutect2, varscan2
- SAC3D1 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs770834599, COSV57245672; called by muse, mutect2, varscan2
- SACS | c.2819C>G p.S940C | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.246); catalogued as COSV66533293; called by muse, mutect2, varscan2
- SERBP1 | c.560C>G p.S187C | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV63412979; called by muse, mutect2, varscan2
- SESN1 | c.1072G>C p.D358H (on ENST00000356644 / NM_001199933.1; = p.D417H on NM_014454.3) | Missense Mutation (SNP) | VAF 49/65 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57420176; called by muse, mutect2, varscan2
- SETBP1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV56311988; called by muse, mutect2, varscan2
- SF3B3 | c.2006T>A p.L669Q | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56784958; called by muse, mutect2, varscan2
- SIGLEC6 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); catalogued as COSV58431638; called by muse, mutect2, varscan2
- SLC12A7 | c.2962G>C p.A988P | Missense Mutation (SNP) | VAF 44/436 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV53754023; called by muse, mutect2, varscan2
- SLC35E4 | c.143G>C p.R48P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV55898507; called by muse, varscan2
- SLC45A1 | c.821C>A p.A274E | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV57092675; called by muse, mutect2
- SNRNP70 | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as COSV55504865; called by muse, mutect2, varscan2
- SPARCL1 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 166/270 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56802165; called by muse, mutect2, varscan2
- SPINK5 | c.1148G>C p.R383T | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56247891; called by muse, mutect2, varscan2
- SPOCD1 | c.3145C>G p.Q1049E | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV57093460, COSV57098956; called by muse, varscan2
- SPOCD1 | c.3100C>G p.Q1034E | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV57093472; called by muse, varscan2
- SRSF2 | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV57974905; called by muse, mutect2, varscan2
- STAG2 | c.3085C>T p.Q1029* | Nonsense Mutation (SNP) | VAF 53/55 reads (96%) | catalogued as COSV54354316; called by muse, mutect2, varscan2
- STC1 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 69/171 reads (40%) | catalogued as COSV99282422; called by muse, mutect2, varscan2
- SYNE1 | c.6048G>A p.Q2016= (on ENST00000367255 / NM_182961.4; = p.Q2023= on NM_033071.3) | Splice Region (SNP) | VAF 90/164 reads (55%) | catalogued as COSV54896987; called by muse, mutect2, varscan2
- TBC1D8B | c.1160G>C p.R387T | Missense Mutation (SNP) | VAF 118/121 reads (98%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV52175280; called by muse, mutect2, varscan2
- TCF4 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV61889893; called by muse, mutect2, varscan2
- THUMPD3 | c.547C>G p.H183D | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV61505475; called by muse, mutect2, varscan2
- TMEM132D | c.1934C>A p.P645H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67158570; called by muse, mutect2, varscan2
- TMEM147 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV52865197; called by muse, mutect2, varscan2
- TNNT1 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 129/220 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV52570185; called by muse, mutect2, varscan2
- TP53BP2 | c.1162G>A p.E388K (on ENST00000343537 / NM_001031685.3; = p.E259K on NM_005426.2) | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as COSV59065870; called by muse, mutect2, varscan2
- TP63 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 91/135 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866938979, COSV53195440; called by muse, mutect2, varscan2
- TSHZ2 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.259); catalogued as rs375294972, COSV61586552; called by muse, mutect2, varscan2
- USF3 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57069414; called by muse, mutect2, varscan2
- VPS13B | c.11840G>C p.R3947T | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1374497851, COSV52553051, COSV99881973; called by muse, varscan2
- WDR45B | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs758343971, COSV66407705; called by muse, mutect2, varscan2
- WDR7 | c.1076C>G p.S359* | Nonsense Mutation (SNP) | VAF 34/67 reads (51%) | catalogued as COSV54355623, COSV54359893; called by muse, mutect2, varscan2
- WIPI1 | c.164-1G>C p.X55_splice | Splice Site (SNP) | VAF 45/61 reads (74%) | catalogued as COSV100048561, COSV50929358; called by muse, mutect2, varscan2
- WNT3A | c.789C>A p.F263L | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV52728202, COSV52728612; called by muse, mutect2, varscan2
- ZBTB47 | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV51763354, COSV99233931; called by muse, varscan2
- ZCWPW2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT tolerated (0.77); PolyPhen benign (0.098); catalogued as COSV67497358; called by muse, mutect2, varscan2
- ZFP64 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53796037; called by muse, mutect2, varscan2
- ZNF234 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 63/312 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV70602754; called by muse, mutect2, varscan2
- ZNF385D | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200229221, COSV55745132; called by muse, mutect2, varscan2
- ZNF511 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.669); catalogued as COSV62919549; called by muse, mutect2, varscan2
- ZNF718 | c.1139C>G p.S380* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as rs1240445681, COSV68140242; called by muse, mutect2, varscan2
- ELF3 | c.653dup p.D218Efs*6 | Frame Shift Ins (INS) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- FRG2C | c.583T>A p.W195R | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.986); called by muse, mutect2
- H1-5 | c.652del p.A218Pfs*? | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | called by mutect2, pindel*, varscan2
- MBOAT1 | c.693_714+5del p.X231_splice | Splice Site (DEL) | VAF 27/220 reads (12%) | called by mutect2, pindel
- MROH1 | c.3888G>C p.R1296S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA31A1 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 102/112 reads (91%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ACSBG2 | c.876C>G p.L292= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99397304; called by muse, mutect2, varscan2
- APBB2 | c.615T>C p.D205= | Silent (SNP) | VAF 96/386 reads (25%) | catalogued as COSV55946424; called by muse, mutect2
- AREL1 | c.2109G>C p.L703= | Silent (SNP) | VAF 49/68 reads (72%) | catalogued as rs763220033, COSV62665304; called by muse, mutect2, varscan2
- ATAT1 | c.417C>G p.L139= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV52540742; called by muse, mutect2, varscan2
- ATP1B3 | c.54C>G p.L18= | Silent (SNP) | VAF 88/106 reads (83%) | catalogued as COSV53948773; called by muse, mutect2, varscan2
- CACNG7 | c.318C>T p.V106= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs748659461, COSV55812815, COSV55817445; called by muse, mutect2, varscan2
- CDH22 | c.1578C>T p.D526= | Silent (SNP) | VAF 44/64 reads (69%) | catalogued as rs374703253; called by muse, mutect2, varscan2
- CDH24 | c.1048C>T p.L350= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV52972700; called by muse, mutect2, varscan2
- CEBPZ | c.1173G>C p.L391= | Silent (SNP) | VAF 75/227 reads (33%) | catalogued as COSV50016848; called by muse, mutect2, varscan2
- CEP55 | c.906G>A p.E302= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV65184400; called by muse, mutect2, varscan2
- CLK3 | c.1716G>A p.V572= (on ENST00000395066 / NM_001130028.1; = p.V424= on NM_003992.4) | Silent (SNP) | VAF 49/92 reads (53%) | catalogued as COSV59338898; called by muse, mutect2, varscan2
- COL14A1 | c.1275C>A p.I425= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV52846391; called by muse, mutect2, varscan2
- CTNND2 | c.1443C>T p.A481= | Silent (SNP) | VAF 140/161 reads (87%) | catalogued as rs140702980; called by muse, mutect2, varscan2
- DEFB113 | c.180C>T p.P60= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs373909445; called by muse, mutect2, varscan2
- DHX35 | c.1329C>G p.L443= | Silent (SNP) | VAF 61/95 reads (64%) | catalogued as COSV52667127; called by muse, mutect2, varscan2
- DNAH17 | c.6153G>C p.L2051= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs756735576, COSV67749215; called by muse, mutect2, varscan2
- ECD | c.1605G>T p.L535= | Silent (SNP) | VAF 47/155 reads (30%) | catalogued as COSV61967969; called by muse, mutect2, varscan2
- EFCAB5 | c.4026C>G p.L1342= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV57925399; called by muse, varscan2
- FNDC8 | c.441G>A p.Q147= | Silent (SNP) | VAF 52/232 reads (22%) | catalogued as COSV50100440; called by muse, mutect2, varscan2
- FYTTD1 | c.57G>A p.P19= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs373199162, COSV54081808; called by muse, mutect2, varscan2
- GABBR1 | c.2466C>A p.V822= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV63540667; called by muse, mutect2, varscan2
- GRIN2D | c.1047C>T p.R349= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs150366451; called by muse, varscan2
- GRIPAP1 | c.2409C>A p.L803= | Silent (SNP) | VAF 18/19 reads (95%) | catalogued as COSV54412186; called by muse, mutect2, varscan2
- GSDME | c.171C>T p.T57= | Silent (SNP) | VAF 39/166 reads (23%) | catalogued as COSV61650748; called by muse, mutect2, varscan2
- HK2 | c.2562C>G p.L854= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as COSV51872826; called by muse, mutect2, varscan2
- HNF1B | c.207C>T p.H69= | Silent (SNP) | VAF 69/95 reads (73%) | catalogued as rs1242601353, CD024193; called by muse, mutect2, varscan2
- HSPA6 | c.1320C>G p.V440= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV59059615; called by muse, mutect2, varscan2
- IDO2 | c.990G>C p.L330= (on ENST00000389060; = p.L343= on NM_194294.2) | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as COSV100584487, COSV58423301; called by muse, mutect2, varscan2
- JAKMIP3 | c.183C>T p.R61= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs779286840, COSV53819304; called by muse, mutect2, varscan2
- KCNH3 | c.1602C>T p.L534= | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as COSV57789209; called by muse, mutect2, varscan2
- KIR3DL1 | c.837T>C p.D279= | Silent (SNP) | VAF 63/331 reads (19%) | called by muse, varscan2
- KRTAP4-1 | c.375C>G p.L125= (on ENST00000398472; = p.L106= on NM_033060.3) | Silent (SNP) | VAF 50/255 reads (20%) | catalogued as COSV66647794; called by muse, mutect2, varscan2
- LZTR1 | c.114C>G p.V38= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV53144770; called by muse, mutect2, varscan2
- MED12 | c.2811C>T p.L937= | Silent (SNP) | VAF 26/28 reads (93%) | catalogued as rs766716404, COSV61329536; called by muse, mutect2, varscan2
- MGAT5 | c.2133C>T p.F711= | Silent (SNP) | VAF 101/160 reads (63%) | catalogued as COSV56093297; called by muse, mutect2, varscan2
- MYBPC2 | c.774C>T p.F258= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs767308870, COSV100731726; called by muse, varscan2
- MYBPC2 | c.3084C>T p.L1028= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs772121872, COSV63093051; called by muse, mutect2, varscan2
- NLRC3 | c.1233G>A p.K411= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV57086573, COSV57089437; called by muse, mutect2, varscan2
- NLRP7 | c.2343C>T p.F781= (on ENST00000340844 / NM_206828.3; = p.F753= on NM_139176.3) | Silent (SNP) | VAF 46/79 reads (58%) | catalogued as COSV60170647, COSV60176575; called by muse, mutect2, varscan2
- OR10S1 | c.204C>T p.L68= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV73342644, COSV73342849, COSV73343087; called by muse, mutect2, varscan2
- OTP | c.180G>A p.G60= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs866920490, COSV100119683, COSV60568332; called by muse, mutect2, varscan2
- PCDHB8 | c.1935C>G p.V645= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as rs537745447, COSV50753542; called by muse, mutect2, varscan2
- PCLO | c.8940G>A p.G2980= | Silent (SNP) | VAF 67/281 reads (24%) | catalogued as rs923242418, COSV61613092; called by muse, mutect2, varscan2
- PDCD7 | c.900C>T p.G300= | Silent (SNP) | VAF 110/250 reads (44%) | catalogued as rs761921567, COSV52599629; called by mutect2, varscan2
- PKD1 | c.5646G>T p.T1882= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV51909754; called by muse, mutect2, varscan2
- PROSER1 | c.1584G>A p.Q528= | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as COSV100612572, COSV61485899; called by muse, mutect2, varscan2
- PSMC4 | c.348G>C p.L116= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV50094207; called by muse, mutect2, varscan2
- PYCR1 | c.870G>A p.V290= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1375721521, COSV61695280; called by muse, mutect2, varscan2
- RBM19 | c.75C>T p.F25= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as rs747722849, COSV55687459; called by muse, mutect2, varscan2
- SCAP | c.2187C>T p.L729= | Silent (SNP) | VAF 17/21 reads (81%) | catalogued as COSV99652577; called by muse, mutect2, varscan2
- SCN4A | c.3117C>T p.F1039= | Silent (SNP) | VAF 37/53 reads (70%) | catalogued as COSV71125442; called by muse, mutect2, varscan2
- SLC22A2 | c.555C>G p.L185= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV65265570; called by muse, mutect2, varscan2
- SLC4A1 | c.699C>T p.R233= | Silent (SNP) | VAF 36/51 reads (71%) | catalogued as rs545536327, COSV52258019; called by muse, mutect2, varscan2
- SLC6A19 | c.1125C>T p.Y375= | Silent (SNP) | VAF 36/472 reads (8%) | catalogued as rs145782869, COSV58670613; called by muse, mutect2
- SLIT2 | c.1035A>G p.Q345= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV56558297; called by muse, mutect2, varscan2
- SMARCD3 | c.1281G>A p.Q427= (on ENST00000262188 / NM_001003801.2; = p.Q414= on NM_003078.4) | Silent (SNP) | VAF 74/148 reads (50%) | catalogued as COSV50388896; called by muse, mutect2, varscan2
- STAG2 | c.3177C>A p.V1059= | Silent (SNP) | VAF 54/54 reads (100%) | catalogued as COSV54349946, COSV54351421; called by muse, mutect2, varscan2
- SYT17 | c.798C>T p.F266= | Silent (SNP) | VAF 54/148 reads (36%) | catalogued as rs748824211, COSV62544846; called by muse, mutect2, varscan2
- TLE6 | c.1185C>T p.F395= (on ENST00000246112 / NM_001143986.2; = p.F272= on NM_024760.3) | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs765998673, COSV55734180; called by muse, mutect2, varscan2
- TNXB | c.10824G>C p.L3608= (on ENST00000647633; = p.L3361= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/119 reads (50%) | catalogued as COSV64472547; called by muse, mutect2, varscan2
- TRPV4 | c.1698C>G p.L566= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs753509572, COSV55679490; called by muse, mutect2, varscan2
- UPF2 | c.1101G>T p.L367= | Silent (SNP) | VAF 58/85 reads (68%) | catalogued as COSV62657830; called by muse, mutect2, varscan2
- URB2 | c.3303C>A p.L1101= | Silent (SNP) | VAF 64/124 reads (52%) | catalogued as COSV50980998; called by muse, mutect2, varscan2
- USH2A | c.11949G>A p.L3983= | Silent (SNP) | VAF 86/157 reads (55%) | catalogued as COSV56322570; called by muse, mutect2, varscan2
- ZNF135 | c.1287G>C p.R429= (on ENST00000313434 / NM_001289401.2; = p.R441= on NM_003436.4) | Silent (SNP) | VAF 50/123 reads (41%) | catalogued as COSV57879820; called by muse, mutect2, varscan2
- ZNF341 | c.2328G>A p.L776= (on ENST00000375200 / NM_001282935.1; = p.L769= on NM_032819.4) | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV61005571; called by muse, mutect2, varscan2
- ZNF792 | c.1773G>A p.E591= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV68692657; called by muse, mutect2, varscan2
- AC024940.1 | n.5076C>G | RNA (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- ATAT1 | c.108-230C>T | Intron (SNP) | VAF 31/56 reads (55%) | catalogued as COSV52540736; called by muse, mutect2, varscan2
- CHCHD2P9 | n.23G>A | RNA (SNP) | VAF 7/24 reads (29%) | catalogued as rs761050744; called by muse, mutect2, varscan2
- DST | c.4297-4965C>T | Intron (SNP) | VAF 51/110 reads (46%) | catalogued as COSV54995664, COSV99760630; called by muse, mutect2, varscan2
- GIT2 | c.1393-1330G>C | Intron (SNP) | VAF 28/70 reads (40%) | catalogued as COSV58077738; called by muse, mutect2
- GP6 | c.*701G>C | 3'UTR (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100117455; called by muse, mutect2, varscan2
- PDE4B | c.281+74280G>A | Intron (SNP) | VAF 47/90 reads (52%) | catalogued as rs764112787, COSV58464567; called by muse, mutect2, varscan2
